Somatic mutation profile of tumor specimen TCGA-VS-A94X-01A (aliquot TCGA-VS-A94X-01A-11D-A387-09) from TCGA case TCGA-VS-A94X, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 40.9 years (14,955 days).
Specimen TCGA-VS-A94X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cff91af-0659-47a0-9b96-c67f25834b9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A94X-10A (Blood Derived Normal), aliquot TCGA-VS-A94X-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5265f1d8-a1a9-447e-8e3f-77afe98b16ae

The open-access MAF lists 310 somatic variants for this specimen: 225 protein-altering or splice-affecting, 76 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 76, Nonsense Mutation 24, 5'Flank 4, Splice Site 4, Intron 4, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 35/59 reads (59%) | catalogued as rs121434259, CM930513, COSV58519659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs786201090, CD044169, CM981870, COSV58820334, COSV58822715; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3194G>A p.W1065* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV100228558; called by muse, mutect2, varscan2
- AAGAB | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99971773; called by muse, mutect2, varscan2
- ABCA6 | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99445875; called by muse, mutect2, varscan2
- ABCB9 | c.1429G>A p.E477K (on ENST00000280560 / NM_019625.4; = p.E434K on NM_019624.3) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV99757561; called by muse, varscan2
- ABL2 | c.3356A>G p.Y1119C (on ENST00000502732 / NM_007314.4; = p.Y1104C on NM_005158.5) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100772489; called by muse, mutect2, varscan2
- ACSM4 | c.1274C>G p.P425R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101257032; called by muse, mutect2, varscan2
- ACTG2 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as rs761640844, COSV100608874, COSV100608995; called by muse, mutect2, varscan2
- ADAM21 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV99960541; called by muse, mutect2, varscan2
- ADAM33 | c.1784C>G p.S595C | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100597692; called by muse, mutect2, varscan2
- ADAM9 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 39/131 reads (30%) | catalogued as COSV101166011, COSV65962467; called by muse, mutect2, varscan2
- ADCY3 | c.2431G>C p.D811H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV53169139, COSV99567713; called by muse, mutect2, varscan2
- AHNAK | c.6239C>A p.S2080* | Nonsense Mutation (SNP) | VAF 63/190 reads (33%) | catalogued as COSV99945750; called by muse, mutect2, varscan2
- ALDH16A1 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1232074627, COSV99201277; called by muse, mutect2, varscan2
- ALX1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100374286; called by muse, mutect2, varscan2
- ANK2 | c.7156G>C p.E2386Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV99999910; called by muse, mutect2, varscan2
- AP1G2 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436574, COSV58112680; called by muse, mutect2, varscan2
- APC | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as CM040978, COSV57328628, COSV57339762, COSV99965505; called by muse, mutect2, varscan2
- APC | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs371117193, COSV99965506; called by muse, mutect2, varscan2
- ATF6 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs1299277099, COSV100909023; called by muse, mutect2, varscan2
- ATN1 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1555143442, COSV63110345; called by muse, mutect2, varscan2
- ATN1 | c.1783C>G p.Q595E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as COSV100755684; called by muse, mutect2, varscan2
- ATP7A | c.2315G>C p.R772T | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV100430286; called by muse, mutect2, varscan2
- BCAN | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.107); catalogued as COSV100227890; called by muse, mutect2, varscan2
- BICRA | c.4640C>G p.S1547C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV101194236; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4589C>T p.S1530L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.946); catalogued as COSV100863595; called by muse, mutect2, varscan2
- BPIFB3 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100972295; called by muse, mutect2, varscan2
- BRF1 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as rs746602408, COSV59265589; called by muse, mutect2, varscan2
- BRIP1 | c.2423G>A p.R808K | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV99369352; called by muse, mutect2, varscan2
- BSN | c.5554C>G p.H1852D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as COSV99607369; called by mutect2, varscan2
- C12orf65 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.763); catalogued as COSV99473856; called by muse, mutect2, varscan2
- C8orf76 | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99414859; called by muse, mutect2, varscan2
- CACNA1C | c.3547G>C p.D1183H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100215642; called by muse, mutect2, varscan2
- CAMTA1 | c.4922G>A p.R1641Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs369220323; called by muse, mutect2, varscan2
- CCDC120 | c.1850C>T p.T617M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs782726173, COSV100896540; called by muse, mutect2, varscan2
- CCDC88A | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99709842; called by muse, mutect2, varscan2
- CD163L1 | c.2501G>A p.R834K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.903); catalogued as COSV100549724; called by muse, mutect2, varscan2
- CD177 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1211212951, COSV100945819, COSV65121303; called by muse, mutect2, varscan2
- CDK12 | c.3969G>C p.L1323F (on ENST00000447079 / NM_016507.4; = p.L1314F on NM_015083.3) | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV70999760; called by muse, mutect2, varscan2
- CDKL4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs777693618, COSV101115130; called by muse, mutect2, varscan2
- CENPE | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99477067; called by muse, mutect2, varscan2
- CHMP6 | c.542A>T p.K181M | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV100289400; called by muse, mutect2, varscan2
- CHST7 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.048); catalogued as rs1048253650, COSV99332778; called by muse, mutect2, varscan2
- CHSY3 | c.2468G>A p.R823K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100518562, COSV59274060; called by muse, mutect2, varscan2
- CIC | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV50660196, COSV99359024; called by muse, mutect2, varscan2
- CILP | c.2911C>A p.R971S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV99972848; called by muse, mutect2, varscan2
- CKAP5 | c.4690-1G>T p.X1564_splice | Splice Site (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100370450; called by muse, mutect2, varscan2
- COA7 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV101034297, COSV65299067; called by muse, mutect2, varscan2
- COL19A1 | c.1349A>G p.D450G | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100505263; called by muse, mutect2, varscan2
- COL4A2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.821); catalogued as COSV100847247; called by muse, mutect2, varscan2
- COL6A3 | c.9122C>T p.T3041M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs754218170, COSV99796313; called by muse, mutect2, varscan2
- COLQ | c.1097A>C p.D366A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs1412394694, COSV101082031; called by muse, mutect2, varscan2
- CORO2A | c.1317G>T p.W439C | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100673979, COSV59662499; called by muse, mutect2, varscan2
- CPLANE1 | c.7838C>T p.S2613L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99949726; called by muse, mutect2, varscan2
- CREB3L4 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV99665608; called by muse, mutect2, varscan2
- CTIF | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV99836873; called by muse, mutect2, varscan2
- CUX1 | c.1027G>A p.E343K (on ENST00000292535 / NM_181552.4; = p.E354K on NM_001913.5) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as COSV52909651; called by muse, mutect2, varscan2
- DEFB116 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.185); catalogued as COSV101269208; called by muse, mutect2, varscan2
- DIAPH3 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs769230544, COSV99932825; called by muse, mutect2, varscan2
- DLL3 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99218766; called by muse, mutect2, varscan2
- DNAH2 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.824); catalogued as COSV50014492; called by muse, mutect2, varscan2
- DNAJB14 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs1378644681, COSV100508268; called by muse, mutect2, varscan2
- DSP | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs751566392, COSV101131900, COSV65795465; ClinVar: uncertain significance; called by muse, varscan2
- DUSP12 | c.468G>C p.E156D | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); catalogued as COSV100909671; called by muse, mutect2, varscan2
- DYNC1H1 | c.13739C>T p.A4580V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100794484; called by muse, mutect2, varscan2
- EFCAB14 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs1166622072, COSV100905547, COSV64237946; called by muse, mutect2, varscan2
- EIF4G1 | c.2240G>A p.R747Q (on ENST00000346169 / NM_198241.3; = p.R552Q on NM_004953.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.394); catalogued as rs781676030, COSV59991837; called by muse, mutect2, varscan2
- EP400 | c.8346C>G p.I2782M | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV100200495; called by muse, mutect2, varscan2
- ERGIC2 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100791937; called by muse, mutect2, varscan2
- ETFDH | c.1404G>C p.M468I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV100306719; called by muse, mutect2, varscan2
- EYA1 | c.1640G>C p.R547T | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV100378606; called by muse, mutect2
- FAM9A | c.411G>C p.M137I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV101121289, COSV101121304; called by muse, mutect2, varscan2
- FAT2 | c.3741C>G p.F1247L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV99941764; called by muse, mutect2, varscan2
- FLNC | c.6773C>T p.S2258L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs762051422, COSV57956300; called by muse, mutect2, varscan2
- FMNL3 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99525657; called by muse, mutect2, varscan2
- FOXA2 | c.1134C>G p.I378M (on ENST00000377115 / NM_153675.3; = p.I384M on NM_021784.5) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101008260; called by muse, mutect2, varscan2
- GABRB2 | c.1513G>A p.V505I (on ENST00000274547; = p.V467I on NM_000813.3) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.08); catalogued as rs1218503196, COSV50904714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCM1 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV99452133; called by muse, mutect2, varscan2
- GFPT2 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 44/97 reads (45%) | catalogued as COSV99517313; called by muse, mutect2, varscan2
- GOT1 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs776949680, COSV100981654; called by muse, mutect2, varscan2
- GPATCH1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs775373927, COSV99403770; called by muse, mutect2, varscan2
- GPLD1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753393225, COSV100015036; called by muse, mutect2, varscan2
- GPRC6A | c.1725G>C p.R575S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100114048; called by muse, mutect2, varscan2
- GRHL1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257546; called by muse, mutect2, varscan2
- GRIA2 | c.1377C>A p.F459L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV99643147; called by muse, mutect2, varscan2
- H3C3 | c.112A>T p.K38* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100778248; called by muse, mutect2, varscan2
- HAPLN2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV54815702; called by mutect2, varscan2
- HCFC1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV100128471; called by muse, varscan2
- HECTD1 | c.2821G>C p.E941Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV101125702; called by muse, mutect2, varscan2
- HECTD1 | c.1863T>G p.I621M | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV101237303; called by muse, mutect2, varscan2
- HMGN2 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1265667994, COSV63523969; called by muse, mutect2, varscan2
- HS3ST3A1 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as rs1438361874, COSV99404056; called by muse, mutect2, varscan2
- HSPA2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 37/111 reads (33%) | catalogued as COSV99904706; called by muse, mutect2, varscan2
- HYDIN | c.9248+1G>A p.X3083_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99992016; called by muse, mutect2, varscan2
- IBTK | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780841874, COSV100090079; called by muse, mutect2, varscan2
- ICA1 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55584608; called by muse, mutect2, varscan2
- IFNA1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99439815; called by muse, mutect2, varscan2
- IRS4 | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | catalogued as COSV100929436; called by muse, mutect2, varscan2
- ISG15 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV101046062; called by muse, mutect2, varscan2
- JAG2 | c.2290G>A p.G764S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100077937; called by muse, mutect2, varscan2
- JPH2 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs886039170, COSV100881605; ClinVar: uncertain significance; called by muse, varscan2
- KATNIP | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV99849942; called by muse, mutect2, varscan2
- KCNU1 | c.2087C>G p.S696C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV101298942; called by muse, mutect2, varscan2
- KHDRBS1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748574978, COSV100306106; called by muse, mutect2, varscan2
- KIAA2026 | c.1955C>G p.P652R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV101198867; called by muse, mutect2, varscan2
- KIR3DL3 | c.1055-1G>A p.X352_splice | Splice Site (SNP) | VAF 61/319 reads (19%) | catalogued as COSV99399674; called by muse, mutect2, varscan2
- KLHL4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100909159; called by muse, mutect2, varscan2
- KMT2D | c.15067G>A p.D5023N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV99977828; called by muse, mutect2, varscan2
- KRT7 | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV59330763; called by muse, mutect2, varscan2
- LANCL3 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1556434446, COSV66129000; called by muse, mutect2, varscan2
- LRP4 | c.4219G>A p.D1407N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.45); catalogued as COSV101066260; called by muse, mutect2, varscan2
- LRP8 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100036114; called by muse, mutect2
- LRRC31 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246326; called by muse, mutect2, varscan2
- LUZP4 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as rs916034489, COSV100904836; called by muse, mutect2
- MAB21L1 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100077052; called by muse, mutect2, varscan2
- MACC1 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100255429; called by muse, mutect2
- MAP4 | c.2544G>C p.K848N | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99274742; called by muse, mutect2, varscan2
- MEGF8 | c.1964C>G p.S655* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as rs751800916, COSV52086214, COSV52094146; called by muse, mutect2, varscan2
- METAP1D | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV100249814; called by muse, mutect2, varscan2
- MFAP1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs780384348, COSV99979632; called by muse, mutect2, varscan2
- MIDEAS | c.2502G>C p.K834N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99678618; called by muse, mutect2, varscan2
- MKI67 | c.2597C>T p.S866L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100896195; called by muse, mutect2, varscan2
- MLH3 | c.2951C>G p.S984* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99469665; called by muse, mutect2, varscan2
- MUC16 | c.24242C>G p.S8081C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.437); catalogued as COSV101198298; called by muse, mutect2, varscan2
- MUC16 | c.23815C>G p.Q7939E | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV101198299; called by muse, mutect2, varscan2
- MUC4 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.65); catalogued as COSV100639614, COSV62200738; called by muse, mutect2, varscan2
- MYH10 | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV52600168, COSV52607109; called by muse, mutect2, varscan2
- MYH15 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV56307095; called by muse, mutect2, varscan2
- NAA25 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.715); catalogued as COSV99927289; called by muse, mutect2, varscan2
- NBEAL2 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.435); catalogued as COSV99434622; called by muse, mutect2, varscan2
- NCALD | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636739, COSV99637677; called by muse, mutect2, varscan2
- NCAPD2 | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99975179; called by muse, mutect2, varscan2
- NCR2 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.734); catalogued as COSV100897191; called by muse, mutect2, varscan2
- NEUROD4 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as rs902216883, COSV54473426; called by muse, mutect2
- NLRP4 | c.2629G>A p.G877R | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.592); catalogued as rs772913904, COSV56718246; called by muse, mutect2, varscan2
- NLRP6 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV100380941; called by muse, mutect2, varscan2
- NLRP6 | c.2058G>C p.K686N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100380942; called by muse, mutect2, varscan2
- NOP2 | c.1409C>G p.S470C (on ENST00000322166 / NM_001258308.2; = p.S466C on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100350798; called by muse, mutect2, varscan2
- NR1H4 | c.595G>C p.E199Q (on ENST00000551379 / NM_001206993.2; = p.E189Q on NM_005123.4) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs767846303, COSV99500069; called by muse, mutect2, varscan2
- NSD3 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100388470; called by muse, mutect2, varscan2
- NXPE4 | c.1534G>C p.D512H (on ENST00000375478 / NM_001077639.2; = p.D228H on NM_017678.3) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970314; called by muse, mutect2, varscan2
- OGN | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV99363970; called by muse, mutect2, varscan2
- OPHN1 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100830222; called by muse, mutect2, varscan2
- OPHN1 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 78/433 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV100830223; called by muse, mutect2, varscan2
- OR8S1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV59599936, COSV59600401; called by muse, mutect2, varscan2
- OTUD3 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100908997; called by muse, mutect2, varscan2
- OVOL1 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100256741, COSV60120408; called by muse, mutect2, varscan2
- OXR1 | c.1393C>G p.Q465E (on ENST00000442977 / NM_001198532.1; = p.Q464E on NM_018002.3) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100366772; called by muse, mutect2
- PAGE2B | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV100894281; called by muse, mutect2, varscan2
- PDZRN4 | c.2413G>T p.E805* (on ENST00000402685 / NM_001164595.2; = p.E547* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100113685; called by muse, mutect2, varscan2
- PIK3R6 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1169475094; called by muse, mutect2
- PLCH1 | c.1855G>A p.D619N (on ENST00000340059 / NM_001130960.2; = p.D631N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV58204127; called by muse, mutect2
- PLEKHG4 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV100846438; called by muse, mutect2, varscan2
- POLR2L | c.6C>G p.I2M | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV100431693; called by muse, mutect2, varscan2
- PPFIA3 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as COSV100494703; called by muse, mutect2, varscan2
- PPP1R3B | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100133889; called by muse, mutect2
- PPP4R3B | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV99701440; called by muse, mutect2, varscan2
- PRICKLE4 | c.743_744insTTT p.L248_A249insF (on ENST00000359201; = p.L288_A289insF on NM_013397.6) | In Frame Ins (INS) | VAF 59/193 reads (31%) | catalogued as COSV59253542; called by mutect2, pindel, varscan2
- PSMA7 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53383349, COSV99443785; called by muse, mutect2, varscan2
- PTPRU | c.2785C>T p.R929* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs750903519, COSV60522219; called by muse, mutect2, varscan2
- RBL1 | c.3202C>T p.H1068Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100726886; called by muse, mutect2, varscan2
- REG4 | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99858385; called by muse, mutect2, varscan2
- RHBDL2 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV100008316; called by muse, mutect2, varscan2
- RIMKLB | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100223750; called by muse, mutect2, varscan2
- RMND5A | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV99373584; called by muse, mutect2, varscan2
- RYR2 | c.10618G>A p.D3540N | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.316); catalogued as COSV63665120; called by muse, mutect2
- SAMD3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs141904490, COSV100931664; called by muse, mutect2, varscan2
- SARS1 | c.81C>G p.F27L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV52320629, COSV99320966; called by muse, mutect2, varscan2
- SCN3A | c.5839G>C p.D1947H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.689); catalogued as COSV99325758; called by muse, mutect2, varscan2
- SEL1L2 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | catalogued as COSV99532636; called by muse, mutect2, varscan2
- SEMA3A | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545407; called by muse, mutect2, varscan2
- SFRP1 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV99616941; called by muse, mutect2, varscan2
- SIN3A | c.1784C>G p.S595C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100845043; called by muse, mutect2, varscan2
- SLC66A1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.841); catalogued as COSV100913169; called by muse, mutect2, varscan2
- SNX21 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.648); catalogued as COSV100701674; called by muse, mutect2, varscan2
- SOX10 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs1348367862, COSV100704042, COSV62807568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.4799G>A p.G1600E (on ENST00000392056 / NM_001142644.2; = p.G1571E on NM_030623.3) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as rs757005243, COSV60870787; called by muse, mutect2, varscan2
- SPIRE2 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 70/242 reads (29%) | catalogued as COSV100988738; called by muse, mutect2, varscan2
- SREBF1 | c.3078G>T p.Q1026H | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs868055320, COSV99883436; called by muse, mutect2, varscan2
- SREBF1 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.27); PolyPhen benign (0.367); catalogued as COSV99888338; called by muse, mutect2, varscan2
- SSPOP | n.15494A>G | Splice Region (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100947028; called by muse, mutect2, varscan2
- ST6GAL1 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 20/99 reads (20%) | PolyPhen possibly damaging (0.654); catalogued as COSV99398210; called by muse, mutect2, varscan2
- STK39 | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.859); catalogued as COSV100596244; called by muse, mutect2, varscan2
- SV2C | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1222965588, COSV100455673; called by muse, mutect2, varscan2
- SZRD1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1156403725, COSV100981494; called by muse, mutect2, varscan2
- TAF1 | c.3702G>C p.M1234I (on ENST00000373790 / NM_138923.4; = p.M1255I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52114837, COSV99334565; called by muse, mutect2, varscan2
- TBC1D25 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100952109; called by muse, mutect2, varscan2
- TBX22 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100960622; called by muse, mutect2
- TBX6 | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as rs1413203016, COSV99661512; called by muse, mutect2, varscan2
- TCHH | c.4592G>A p.R1531K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs1250737683, COSV100914907, COSV64275823; called by muse, mutect2, varscan2
- TCHH | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs759004035, COSV100914908; called by muse, mutect2, varscan2
- TCOF1 | c.4441-1G>C p.X1481_splice (on ENST00000377797 / NM_001135243.1; = p.X1404_splice on NM_000356.4) | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99153515; called by muse, mutect2, varscan2
- TDRD5 | c.1836G>C p.Q612H | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99675533; called by muse, mutect2, varscan2
- TEKT4 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99726163; called by muse, mutect2, varscan2
- TESK1 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99427288; called by muse, mutect2, varscan2
- TG | c.4698G>T p.L1566F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV99599225; called by muse, mutect2, varscan2
- THAP7 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99301335; called by muse, mutect2, varscan2
- TMEM87A | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV101100219; called by muse, mutect2
- TNS2 | c.4223G>A p.R1408K (on ENST00000314250 / NM_170754.4; = p.R1418K on NM_015319.2) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.567); catalogued as rs778756703, COSV100036570; called by muse, mutect2, varscan2
- TRAF2 | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV56043594; called by muse, mutect2, varscan2
- TRIM25 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100380904; called by muse, mutect2, varscan2
- TRIO | c.4729G>C p.E1577Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100709926; called by muse, mutect2, varscan2
- TSC22D1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV101488068; called by muse, mutect2, varscan2
- TTI1 | c.3219G>C p.Q1073H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV100989580; called by muse, mutect2, varscan2
- TTLL7 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV99551887; called by muse, mutect2, varscan2
- TTN | c.36209C>G p.S12070C (on ENST00000591111; = p.S4646C on NM_003319.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | PolyPhen probably damaging (0.998); catalogued as COSV100595738; called by muse, mutect2, varscan2
- TUBE1 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100898256; called by muse, mutect2, varscan2
- ULBP1 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.234); catalogued as COSV57664632, COSV99998016; called by muse, mutect2, varscan2
- USP43 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.164); catalogued as rs868521065, COSV53303054, COSV99556392; called by muse, mutect2, varscan2
- VPS51 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV99660864; called by muse, mutect2, varscan2
- WDR44 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV54164119, COSV99561211; called by muse, mutect2, varscan2
- WNT4 | c.374C>G p.T125R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99268595; called by muse, mutect2
- ZBTB47 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99233924; called by muse, mutect2, varscan2
- ZBTB7A | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 38/84 reads (45%) | catalogued as COSV59326485; called by muse, mutect2, varscan2
- ZC3HC1 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100315610, COSV61297948; called by muse, mutect2, varscan2
- ZNF229 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99350068; called by muse, mutect2, varscan2
- ZNF256 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99990640; called by muse, mutect2, varscan2
- ZNF579 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1343381211, COSV100329199; called by mutect2, varscan2
- ZNF630 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99332223; called by muse, mutect2, varscan2
- ZNF75D | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66132847; called by muse, mutect2, varscan2
- ARFGEF1 | c.1923_1927del p.Q642Kfs*9 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by pindel, varscan2
- PPP1R3A | c.2408dup p.E804Gfs*8 | Frame Shift Ins (INS) | VAF 14/67 reads (21%) | called by pindel, varscan2
- UTP3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- WEE1 | c.1073_1089del p.H358Lfs*7 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- AGER | c.1164G>T p.L388= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV100426103; called by muse, mutect2, varscan2
- AHDC1 | c.919C>T p.L307= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99898916; called by muse, mutect2, varscan2
- AKAP8 | c.981C>T p.F327= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs1249798963, COSV99511728; called by muse, mutect2, varscan2
- APBB2 | c.1416G>C p.L472= (on ENST00000295974 / NM_001166050.2; = p.L473= on NM_004307.2) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99922495; called by muse, mutect2, varscan2
- ASCC3 | c.147G>A p.K49= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100225273, COSV61226211; called by muse, mutect2, varscan2
- BHLHA15 | c.303C>G p.V101= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1209881579, COSV99806078; called by muse, mutect2, varscan2
- BSN | c.1347G>A p.S449= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs376633533, COSV99607367; called by muse, mutect2, varscan2
- CARD8 | c.1080G>A p.Q360= (on ENST00000651546 / NM_001184900.3; = p.Q310= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV100751001; called by muse, mutect2, varscan2
- CASR | c.840C>T p.I280= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs201366476, COSV99948492; called by muse, mutect2, varscan2
- CATSPER4 | c.477C>G p.L159= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100128219; called by muse, mutect2, varscan2
- CATSPER4 | c.618C>T p.V206= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100128221; called by muse, mutect2, varscan2
- CCNI2 | c.699G>T p.L233= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV101107754; called by muse, mutect2, varscan2
- CDH16 | c.1995G>A p.L665= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs959373883, COSV100233661; called by muse, mutect2, varscan2
- CMYA5 | c.8112A>G p.G2704= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV101483856; called by muse, mutect2, varscan2
- CNGA2 | c.285C>T p.L95= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as rs367695597, COSV61706273; called by muse, mutect2
- CSPG4 | c.4251C>G p.L1417= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as COSV100413462; called by muse, mutect2
- CYP2U1 | c.925C>T p.L309= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100256610; called by muse, mutect2, varscan2
- DDX54 | c.1357C>T p.L453= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV100013610; called by muse, mutect2, varscan2
- DECR2 | c.138G>A p.E46= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1024063589, COSV99556706; called by muse, mutect2, varscan2
- DISP2 | c.2070C>A p.L690= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99139720; called by muse, mutect2, varscan2
- DNAH11 | c.4884C>T p.F1628= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs762090852, COSV100177389, COSV100180270; called by muse, mutect2, varscan2
- DOLPP1 | c.114C>T p.L38= | Silent (SNP) | VAF 79/164 reads (48%) | catalogued as COSV100588383; called by muse, mutect2, varscan2
- F5 | c.4872C>T p.L1624= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs200569225; called by muse, mutect2, varscan2
- FAM151A | c.1282C>T p.L428= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs753969276, COSV100156758; called by muse, mutect2, varscan2
- FAM83D | c.141C>T p.F47= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99464995; called by muse, mutect2
- FANCA | c.4017C>T p.L1339= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as CD043675, COSV99234586; called by muse, mutect2, varscan2
- FAT2 | c.3873C>T p.F1291= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV55816769; called by muse, mutect2, varscan2
- FLNA | c.5364G>A p.L1788= (on ENST00000369850 / NM_001110556.2; = p.L1780= on NM_001456.3) | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100774305, COSV61036141; called by muse, mutect2, varscan2
- GLIS2 | c.42C>T p.I14= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV99267307; called by muse, mutect2, varscan2
- GLIS2 | c.474C>G p.L158= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV52109913; called by muse, mutect2, varscan2
- HERC4 | c.3033C>T p.S1011= (on ENST00000395198 / NM_022079.3; = p.S1003= on NM_015601.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99281606; called by muse, mutect2, varscan2
- HHIP | c.120G>A p.L40= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV56842132, COSV99666650; called by muse, mutect2, varscan2
- HMGCL | c.375C>G p.V125= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as CD077406, COSV99353688; called by muse, mutect2, varscan2
- HSPA2 | c.222G>C p.L74= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV99904709; called by muse, mutect2, varscan2
- ITGA3 | c.87C>A p.V29= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs982779323, COSV50306226; called by muse, mutect2, varscan2
- KMT2D | c.15993C>G p.L5331= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV99977824; called by muse, mutect2, varscan2
- KMT2D | c.15849C>A p.L5283= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV56440346, COSV99977826; called by muse, mutect2, varscan2
- LASP1 | c.402C>T p.S134= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs755621366, COSV100530309, COSV58802678; called by muse, mutect2
- LRIG1 | c.1224G>A p.L408= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99833269; called by muse, mutect2, varscan2
- LRP5 | c.339C>T p.L113= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs753488677, COSV99591465; called by muse, mutect2, varscan2
- MCM2 | c.2685G>A p.L895= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99412823; called by muse, mutect2
- MTNR1B | c.237G>A p.L79= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1483511421, COSV99924959; called by muse, mutect2, varscan2
- MUC16 | c.23427C>A p.L7809= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV101198300; called by muse, mutect2, varscan2
- MYPN | c.3762C>T p.I1254= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1288590009, COSV62741477; called by muse, mutect2, varscan2
- NECAB3 | c.1029C>T p.F343= (on ENST00000246190 / NM_031232.4; = p.F309= on NM_031231.4) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs1390741615, COSV99864514; called by muse, mutect2, varscan2
- NPAS1 | c.1203C>G p.V401= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV99451325; called by muse, mutect2, varscan2
- NUDT14 | c.129G>A p.V43= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100241974, COSV100241979; called by muse, mutect2, varscan2
- OXTR | c.939C>T p.I313= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs748383989, COSV57478227; called by muse, mutect2, varscan2
- PAXBP1 | c.291G>A p.E97= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99269047; called by muse, mutect2
- PCDH18 | c.3324C>T p.L1108= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1328331512, COSV100787053; called by muse, mutect2, varscan2
- PCYOX1L | c.1014C>T p.H338= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as rs758406868, COSV51003947; called by muse, mutect2, varscan2
- PLA2G4D | c.1947C>T p.A649= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99299294; called by muse, mutect2
- POGLUT2 | c.93G>A p.K31= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99958566; called by muse, mutect2, varscan2
- PPP1R1A | c.216G>A p.K72= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV99226274; called by muse, mutect2, varscan2
- RSF1 | c.1467C>T p.S489= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs868769172, COSV57846373; called by muse, mutect2
- RTN1 | c.2070G>C p.L690= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99954699; called by muse, mutect2, varscan2
- RYR3 | c.5079G>A p.T1693= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs771420569, COSV66785439; called by muse, mutect2, varscan2
- SLC12A5 | c.864C>G p.L288= (on ENST00000454036 / NM_001134771.2; = p.L265= on NM_020708.5) | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99715408; called by muse, mutect2, varscan2
- SLC17A9 | c.963C>T p.L321= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100947712; called by muse, mutect2, varscan2
- SLC25A43 | c.759C>T p.F253= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV99474419; called by muse, mutect2, varscan2
- SLC35A5 | c.558C>T p.F186= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99656701; called by muse, mutect2, varscan2
- SMOC1 | c.588C>T p.I196= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100734338; called by muse, mutect2, varscan2
- SP7 | c.972C>T p.F324= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs774411292, COSV58190447; called by muse, mutect2, varscan2
- SPRY1 | c.483G>A p.L161= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100201752; called by muse, mutect2, varscan2
- SRCAP | c.3795G>A p.P1265= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs774030183, COSV99349361; called by muse, mutect2, varscan2
- SULT2A1 | c.528G>A p.E176= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV99705306; called by muse, mutect2, varscan2
- TBX5 | c.432C>T p.T144= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs146038442, CD991892, COSV100090590; called by muse, mutect2, varscan2
- TCF25 | c.2030G>A p.*677= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV54531178, COSV99642391; called by muse, mutect2, varscan2
- TESPA1 | c.1183C>T p.L395= (on ENST00000316577 / NM_001098815.3; = p.L257= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100344899; called by muse, mutect2, varscan2
- TRAK1 | c.2007C>T p.F669= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs940774193, COSV100565276; called by muse, varscan2
- TRIB2 | c.129C>T p.L43= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs780227431, COSV50223887; called by muse, mutect2, varscan2
- TXNIP | c.18G>A p.K6= | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as COSV100997259; called by muse, mutect2, varscan2
- USP44 | c.1854C>T p.I618= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs778245807, COSV99311610; called by muse, mutect2, varscan2
- VASH2 | c.69G>C p.R23= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99663394; called by muse, mutect2, varscan2
- VPS8 | c.1768C>T p.L590= (on ENST00000625842 / NM_001349294.1; = p.L588= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as COSV54993510, COSV54995560; called by muse, mutect2, varscan2
- ZNF75D | c.96G>A p.Q32= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV100883582; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840664 G>C | 5'Flank (SNP) | VAF 25/147 reads (17%) | catalogued as COSV100005379; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208230 C>G | 5'Flank (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- DST | c.16635+442G>A | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99751510; called by muse, mutect2, varscan2
- PAK6 | c.-117-864G>C | Intron (SNP) | VAF 8/14 reads (57%) | catalogued as COSV53045268, COSV99544236; called by muse, mutect2, varscan2
- RBCK1 | c.168-250G>C | Intron (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- RPP38 | chr10:15096467 G>A | 5'Flank (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- UCHL5 | chr1:193059926 C>A | 5'Flank (SNP) | VAF 18/97 reads (19%) | catalogued as COSV100814558; called by muse, mutect2, varscan2
- UGGT2 | c.1092+229G>A | Intron (SNP) | VAF 11/82 reads (13%) | catalogued as rs980508525, COSV100943472; called by muse, mutect2, varscan2
- XIST | n.9328C>G | RNA (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
